Surgical pathology report (de-identified scan), TCGA case TCGA-32-1991, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1991-01A (Primary Tumor).

SPECIMEN SOURCE:

Brain mass

GBM
CONTROL

CLINICAL DIAGNOSIS:

Brain mass

TCGA-32-1991

GROSS DESCRIPTION:

Received fresh for frozen section are two portions of tan-pink soft tissue measuring 0.5 x 0.4 x 0.2 cm and 0.4 x 0.3 x 0.2 cm. A smear preparation is performed. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

The previously frozen tissue is subsequently submitted for permanent sections.

MICROSCOPIC DESCRIPTION:

Permanent sections of frozen section specimen confirms the presence of a cellular high grade glial neoplasm. The tumor cells resemble atypical fibrillary astrocytes. Large areas of tumor necrosis are seen.

DIAGNOSIS:

(PROVISIONAL)

BRAIN MASS, FROZEN SECTION BIOPSY:

GLIOBLASTOMA, PENDING REVIEW OF ADDITIONAL TISSUE.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

1. Please see previous report.
2. Brain mass

ADDENDUM GROSS DESCRIPTION:

1. Please see previous report.
2. Received in formalin labeled with the patient's name and "brain mass" are multiple portions of tan-brown soft tissue aggregating to 2.0 x 2.0 x 0.5 cm. The specimen is entirely submitted in one cassette.

MICROSCOPIC EXAMINATION:

2. Sections demonstrate a markedly hypercellular glial neoplasm. It is composed of cells resembling atypical fibrillary and small anaplastic astrocytes. Some perinuclear clearing is seen but well-formed halos or definite oligodendroglioma differentiation is not noted. Microvascular proliferation is present. There are large foci of confluent tumor necrosis. Numerous mitotic figures are seen.

ADDENDUM DIAGNOSIS:

- 1, 2. LEFT FRONTAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (ASTROCYTOMA GRADE IV)

ADDENDUM #2 NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Overall, approximately 10-25% of the tumor cells are immunoreactive for MGMT.

ADDENDUM DIAGNOSIS:

- 1, 2. LEFT FRONTAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (ASTROCYTOMA GRADE IV)

Source: NCI Genomic Data Commons file d94abdca-3c8c-4a04-b116-da647d6388eb (TCGA-32-1991.2BE50793-4E68-43F0-96F8-992C82C0AA85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).